Gene-level copy-number profile of tumor specimen TCGA-XF-A9SH-01A from TCGA case TCGA-XF-A9SH, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 65.9 years (24,060 days).
Specimen TCGA-XF-A9SH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.cca924db-1939-484e-a246-d2e1eacb2b6e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A9SH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1a63f461-dae4-431e-8cfa-691b45a8424d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 3,117; copy number 2: 51,057; copy number 3: 4,470; copy number 4: 560; copy number 5: 12; copy number 6: 241; copy number 7: 48; copy number 8: 33; copy number 9: 115; copy number 11: 64; copy number 12: 19; copy number 17: 13; copy number 18: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A9SH-01A-11D-A390-01): tumor purity 0.69, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:97,904,489–99,154,192, 24 genes (within-gene range 0–1): TRMO, Y_RNA, AL499604.1, HEMGN, ANP32B, AL354726.1, RNU6-918P, NANS, TRIM14, Metazoa_SRP, CORO2A, TBC1D2, MIR6854, AL360081.1, GABBR2, SEPTIN7P7, ANKS6, AL807776.1, GALNT12, AL136084.1, NME2P3, COL15A1, AL136084.2, TGFBR1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 587 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:68,332,888–68,451,663, 1 gene, copy number 18 (within-gene range 1–18): LINC02384.
- chr12:68,426,331–70,637,440, 56 genes, copy number 12–18: AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.
- chr12:70,671,918–70,672,856, 1 gene, copy number 12: FAHD2P1.
- chr12:73,820,315–74,402,600, 1 gene, copy number 17 (within-gene range 1–17): LINC02882.
- chr12:74,039,024–75,984,015, 32 genes, copy number 9–17: LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3, AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1, AC011611.6, RN7SL734P, AC011611.2, AC011611.1.
- chr12:76,259,836–78,213,010, 22 genes, copy number 9 (within-gene range 3–9): LNCOG, RN7SKP172, BBS10, OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1, AC025161.1, E2F7, AC079030.1, LINC02464, NAV3, AC073591.1, AC138331.1, AC073571.1.
- chr12:78,793,526–78,808,995, 2 genes, copy number 18: AC068993.1, AC068993.2.
- chr12:78,960,258–79,045,644, 1 gene, copy number 18: AC090709.1.
- chr12:87,782,163–93,408,146, 91 genes, copy number 8–9 (broad region; genes not listed).
- chr12:94,521,090–97,680,047, 74 genes, copy number 5–8 (broad region; genes not listed).
- chr12:97,721,716–97,721,822, 1 gene, copy number 6: RNU6-36P.
- chr12:99,647,753–100,628,288, 20 genes, copy number 7: FAM71C, AC078916.1, RPS4XP1, AC126474.1, UHRF1BP1L, AC126474.2, AC010203.2, GOLGA2P5, RN7SL176P, AC010203.1, MIR1827, ACTR6, DEPDC4, Y_RNA, SCYL2, SLC17A8, NR1H4, AC010200.1, GAS2L3, PIGAP1.
- chr12:101,696,947–102,824,399, 28 genes, copy number 7 (within-gene range 4–7): CHPT1, RNY1P16, SYCP3, GNPTAB, RNU6-101P, AC063950.1, RNA5SP368, RNU6-172P, RNA5SP369, RNU6-1183P, HSPE1P4, DRAM1, AC084398.2, AC084398.1, AC079907.2, NENFP2, WASHC3, AC079907.1, NUP37, PARPBP, PMCH, HELLPAR, RN7SL793P, AC093023.1, LINC02456, IGF1, AC010202.1, LINC00485.
- chr12:106,170,004–112,898,881, 165 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:113,298,759–118,430,699, 92 genes, copy number 6–11 (within-gene range 4–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,117. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
